Somatic mutation profile of tumor specimen MP2PRT-PAPHTL-TMP1-A (aliquot MP2PRT-PAPHTL-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPHTL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (964 days).
Specimen MP2PRT-PAPHTL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba533756-f5c5-453d-bedd-67e60aa4ef28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHTL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHTL-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4113f7e-345e-4c40-a1bc-5f734e12964e

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C10orf71 | c.3979G>A p.A1327T | Missense Mutation (SNP) | VAF 289/568 reads (51%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as rs1423128225, COSV60515545; called by muse, mutect2, varscan2
- GC | c.355C>T p.R119* | Nonsense Mutation (SNP) | VAF 92/426 reads (22%) | catalogued as rs774755036, COSV56740398; called by muse, mutect2, varscan2
- LDB2 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 110/458 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs143514792, COSV58772066; called by muse, mutect2, varscan2
- NAPSA | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 149/537 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53798836; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406868 CCATTCACAGTGTTACAAGCCATA>TCTAGGG | Missense Mutation (DEL) | VAF 52/136 reads (38%) | called by pindel, varscan2*
- SMIM23 | c.329A>G p.E110G | Missense Mutation (SNP) | VAF 118/453 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- TP53INP1 | c.425G>T p.S142I | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- UBN1 | c.3099_3100insACCGACCG p.L1034Tfs*8 | Frame Shift Ins (INS) | VAF 72/392 reads (18%) | called by mutect2, pindel*, varscan2
- KCNT2 | c.2985C>T p.N995= | Silent (SNP) | VAF 90/333 reads (27%) | called by muse, mutect2, varscan2
- PAK5 | c.99C>T p.T33= | Silent (SNP) | VAF 99/616 reads (16%) | catalogued as rs150549417; called by muse, mutect2, varscan2
- PRTN3 | c.702G>A p.T234= | Silent (SNP) | VAF 149/748 reads (20%) | catalogued as rs750289977; called by muse, mutect2, varscan2
- VIM | c.9C>T p.T3= | Silent (SNP) | VAF 97/493 reads (20%) | called by muse, mutect2, varscan2
